Somatic mutation profile of tumor specimen 87408d9e-4029-4e8f-b14c-8efc04 (aliquot 87408d9e-4029-4e8f-b14c-8efc04_D6) from CPTAC case 06CO001, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 87408d9e-4029-4e8f-b14c-8efc04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e03b5d9c-0236-48dd-9fc2-93305ec61731.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a5ceba47-6596-47ff-8fab-e835d3 (Blood Derived Normal), aliquot a5ceba47-6596-47ff-8fab-e835d3_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16ff7e7f-b5e9-442e-8dfc-497b17a3da45

The open-access MAF lists 111 somatic variants for this specimen: 69 protein-altering or splice-affecting, 26 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 26, Intron 10, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 3, 5'UTR 3, 3'Flank 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 108/235 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs758305694, COSV100229195, COSV55290676; called by muse, mutect2, varscan2
- ADAMTS14 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as rs749720359, COSV64602745; called by muse, mutect2, varscan2
- ADCY8 | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 365/471 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889544437, COSV53900258; called by muse, mutect2, varscan2
- APC | c.2879C>A p.S960* | Nonsense Mutation (SNP) | VAF 151/506 reads (30%) | catalogued as COSV57377386, COSV57388148; called by mutect2, varscan2
- APC | c.4037C>A p.S1346* | Nonsense Mutation (SNP) | VAF 138/440 reads (31%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by mutect2, varscan2
- CSNK1G3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV100631764; called by muse, mutect2, varscan2
- DSCAM | c.5461G>A p.A1821T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1208234992, COSV68032312; called by muse, mutect2, varscan2
- DUOX1 | c.3089C>T p.T1030M | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs754144716; called by muse, mutect2, varscan2
- EP300 | c.3442G>A p.V1148I | Missense Mutation (SNP) | VAF 140/475 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs750777340; called by muse, mutect2, varscan2
- FAM117A | c.1202G>T p.C401F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.808); catalogued as rs1322716865; called by muse, mutect2, varscan2
- FBN1 | c.6379G>T p.D2127Y | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM003140, CM154850; called by muse, mutect2, varscan2
- GOLGA3 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs759417382, COSV52635933, COSV52644602; called by muse, mutect2, varscan2
- GTF2E2 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs749607324, COSV63478237; called by muse, mutect2, varscan2
- IL9R | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 267/343 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs143124772; called by muse, mutect2, varscan2
- IRGC | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as rs759571667; called by muse, mutect2, varscan2
- ITGA10 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs782722593; called by muse, mutect2, varscan2
- MC3R | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 22/439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1481948431, COSV54763393; called by muse, mutect2
- NFIL3 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs567150726; called by muse, mutect2, varscan2
- NFKBIL1 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as rs1253285930; called by muse, mutect2, varscan2
- NLRP10 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs1386744348, COSV100149487; called by muse, mutect2, varscan2
- PAX7 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 124/202 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1473016979, COSV64750307; called by muse, mutect2, varscan2
- PHF24 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs745628243; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.272); catalogued as COSV67760777; called by muse, mutect2
- SLC12A2 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52475092; called by muse, mutect2, varscan2
- SLC13A4 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372605570; called by muse, mutect2, varscan2
- SLC15A3 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1364713867; called by muse, mutect2, varscan2
- SLC25A6 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs763375002; called by muse, mutect2, varscan2
- SLC32A1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 329/535 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as rs778245804, COSV99462782; called by muse, mutect2, varscan2
- SOD3 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66125849; called by muse, mutect2, varscan2
- TRPA1 | c.2618C>A p.S873Y | Missense Mutation (SNP) | VAF 223/305 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51557053; called by muse, mutect2, varscan2
- VWDE | c.4429C>T p.R1477C | Missense Mutation (SNP) | VAF 252/442 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1225680626; called by muse, mutect2, varscan2
- ZPBP | c.493C>G p.R165G | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV50427081; called by muse, mutect2, varscan2
- AATF | c.1412_1420del p.L471_E473del | In Frame Del (DEL) | VAF 31/123 reads (25%) | called by mutect2, pindel, varscan2
- AKR1B10 | c.909-1G>C p.X303_splice | Splice Site (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- BOC | c.790T>C p.W264R | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf58 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CCDC18 | c.3772A>C p.K1258Q (on ENST00000343253 / NM_001306076.1; = p.K1259Q on NM_206886.4) | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.11); called by muse, mutect2
- CD180 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CELA2A | c.493+1G>T p.X165_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.965T>A p.V322E | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DIDO1 | c.6482G>A p.R2161H | Missense Mutation (SNP) | VAF 362/574 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DOCK3 | c.4560G>T p.E1520D | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EPC2 | c.749T>C p.M250T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- FAM71E2 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by mutect2, varscan2
- JAKMIP1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- LMO7 | c.388C>T p.P130S (on ENST00000357063; = p.P145S on NM_005358.5) | Missense Mutation (SNP) | VAF 176/409 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LPAR6 | c.547A>G p.R183G | Missense Mutation (SNP) | VAF 358/614 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- LTBP4 | c.902_909del p.P301Rfs*46 (on ENST00000308370 / NM_001042544.1; = p.P264Rfs*46 on NM_003573.2) | Frame Shift Del (DEL) | VAF 50/169 reads (30%) | called by mutect2, pindel, varscan2
- MUC16 | c.33985G>T p.D11329Y | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MYOM1 | c.3316A>C p.K1106Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NBAS | c.4369T>C p.Y1457H | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBEA | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NCOR1 | c.6536+1del p.X2179_splice | Splice Site (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- OR4D11 | c.187_196del p.L63* | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel, varscan2
- OR5L1 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by mutect2, varscan2
- PDZD7 | c.1515A>G p.I505M | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PENK | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 44/483 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2
- PHF8 | c.2428A>G p.T810A (on ENST00000357988 / NM_001184896.1; = p.T774A on NM_015107.3) | Missense Mutation (SNP) | VAF 141/200 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.45); called by muse, mutect2
- PTPRR | c.144A>T p.Q48H | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SCN7A | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SOX14 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); called by muse, mutect2
- SP140 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- SPATA18 | c.1564-1G>C p.X522_splice | Splice Site (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.856A>C p.M286L | Missense Mutation (SNP) | VAF 116/531 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VCAN | c.6272C>A p.T2091N | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZBTB7A | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 72/205 reads (35%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.975_1000del p.A326Vfs*139 | Frame Shift Del (DEL) | VAF 43/66 reads (65%) | called by mutect2, varscan2
- ACOT12 | c.210T>C p.V70= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- B4GAT1 | c.1014C>T p.F338= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs898939850, COSV60820392; called by muse, mutect2, varscan2
- CDH10 | c.1821C>T p.A607= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs150595829; called by muse, mutect2, varscan2
- DLX4 | c.555G>A p.G185= (on ENST00000240306 / NM_138281.3; = p.G113= on NM_001934.3) | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- FBLL1 | c.756G>A p.P252= | Silent (SNP) | VAF 108/287 reads (38%) | catalogued as rs1181266431; called by muse, mutect2, varscan2
- FHDC1 | c.693C>T p.D231= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as rs767725606, COSV52600959; called by muse, mutect2, varscan2
- FLG | c.5244A>G p.Q1748= | Silent (SNP) | VAF 28/352 reads (8%) | catalogued as COSV64239426; called by muse, mutect2
- FOXE1 | c.300C>T p.S100= | Silent (SNP) | VAF 75/238 reads (32%) | called by muse, mutect2, varscan2
- HMCN1 | c.13989T>C p.T4663= | Silent (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- ITGA8 | c.1959G>T p.L653= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as COSV65223961; called by muse, mutect2, varscan2
- KMT2D | c.11322G>A p.Q3774= | Silent (SNP) | VAF 39/278 reads (14%) | catalogued as rs1159914012; called by muse, mutect2, varscan2
- KRT6B | c.318C>T p.A106= | Silent (SNP) | VAF 127/687 reads (18%) | catalogued as rs753114842; called by muse, mutect2, varscan2
- LHFPL3 | c.288C>T p.F96= | Silent (SNP) | VAF 104/662 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.4797C>T p.S1599= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as rs755529583, COSV101202153; called by muse, mutect2, varscan2
- NEK10 | c.888C>T p.L296= | Silent (SNP) | VAF 62/229 reads (27%) | called by muse, mutect2, varscan2
- OR10A3 | c.450C>A p.I150= | Silent (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- PCED1A | c.375G>A p.L125= | Silent (SNP) | VAF 87/185 reads (47%) | catalogued as rs1279931095, COSV100642915; called by muse, mutect2, varscan2
- RFX7 | c.3453A>G p.K1151= (on ENST00000559447 / NM_001368074.1; = p.K1248= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/273 reads (30%) | called by muse, mutect2, varscan2
- SKOR1 | c.1689C>T p.D563= | Silent (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- TIAM1 | c.2712C>T p.D904= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs187475114; called by muse, mutect2, varscan2
- TNFAIP3 | c.133C>A p.R45= | Silent (SNP) | VAF 44/297 reads (15%) | catalogued as rs1173941971, COSV52801294, COSV52801690; called by muse, mutect2, varscan2
- VWA5B2 | c.348G>A p.T116= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs1041787324; called by muse, mutect2, varscan2
- WDR97 | c.489G>A p.V163= | Silent (SNP) | VAF 38/710 reads (5%) | catalogued as rs1028491338; called by muse, mutect2
- ZFP30 | c.1221G>A p.E407= | Silent (SNP) | VAF 39/210 reads (19%) | called by muse, mutect2, varscan2
- ZNF835 | c.666C>T p.Y222= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV73379343, COSV73379619; called by muse, mutect2, varscan2
- ZSWIM4 | c.2677C>T p.L893= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs1229010550; called by muse, mutect2, varscan2
- BCR | c.1279+16039G>A | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as rs764057926; called by muse, mutect2
- C19orf12 | chr19:29700863 C>T | 3'Flank (SNP) | VAF 92/337 reads (27%) | called by muse, mutect2, varscan2
- CGB7 | c.-830C>A | 5'UTR (SNP) | VAF 9/65 reads (14%) | called by mutect2, varscan2
- CSH1 | c.456+48G>A | Intron (SNP) | VAF 61/537 reads (11%) | catalogued as rs780258409; called by muse, mutect2, varscan2
- GABRG2 | c.1249-1408T>C | Intron (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+1131C>T | Intron (SNP) | VAF 48/314 reads (15%) | catalogued as rs542886410; called by muse, mutect2, varscan2
- OFCC1 | n.1058G>T | RNA (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- OLA1 | c.966+61dup | Intron (INS) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- RAPGEF3 | c.-10-15C>T | Intron (SNP) | VAF 20/81 reads (25%) | catalogued as rs750531972; called by muse, mutect2
- RN7SL211P | chr2:64904541 A>C | 3'Flank (SNP) | VAF 82/330 reads (25%) | catalogued as rs1482052492; called by mutect2, varscan2
- RPAIN | c.-141C>A | 5'UTR (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- RPS2 | c.710-89T>C | Intron (SNP) | VAF 99/158 reads (63%) | called by muse, mutect2, varscan2
- RPS2 | c.710-90C>G | Intron (SNP) | VAF 94/155 reads (61%) | catalogued as COSV99238794; called by muse, mutect2, varscan2
- SLC5A2 | c.1280+44C>T | Intron (SNP) | VAF 96/363 reads (26%) | called by muse, mutect2, varscan2
- SRP19 | c.42-71C>T | Intron (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- TSPY8 | c.-38G>A | 5'UTR (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2, varscan2
